Somatic mutation profile of tumor specimen 0DXJGU from CCDI case PBCRBY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinomatosis; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.1 years (5,871 days).
Specimen 0DXJGU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37df9894-7ae4-4cb8-ad80-4cdde25c1a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJED (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf8c5d9d-a039-454b-b21f-2ab044642240

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, Silent 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 280/1077 reads (26%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, varscan2
- CGB7 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 82/1388 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs1386564400; called by muse, varscan2
- OTOF | c.3682C>T p.R1228C (on ENST00000272371 / NM_194248.3; = p.R481C on NM_004802.4) | Missense Mutation (SNP) | VAF 276/1858 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs774452184, COSV55495727; called by muse, varscan2
- PCDHA3 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 378/1848 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as COSV65366805; called by muse, varscan2
- PCDHA9 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 138/1302 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.658); catalogued as rs782485861, COSV65328721; called by muse, varscan2
- PCDHB16 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 283/1480 reads (19%) | catalogued as COSV53373693; called by muse, varscan2
- ATXN2L | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 463/3038 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); called by muse, varscan2
- CDH1 | c.1625T>A p.I542N | Missense Mutation (SNP) | VAF 419/2207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FAM184A | c.765_766dup p.Q256Lfs*12 | Frame Shift Ins (INS) | VAF 298/2642 reads (11%) | called by pindel, varscan2
- SBNO2 | c.2487G>A p.W829* | Nonsense Mutation (SNP) | VAF 186/1770 reads (11%) | called by muse, varscan2
- ABCB1 | c.474G>A p.Q158= | Silent (SNP) | VAF 490/2625 reads (19%) | called by muse, varscan2
- CTSL | c.903-99G>T | Intron (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- PDE4DIP | c.637-7075G>A | Intron (SNP) | VAF 202/1847 reads (11%) | catalogued as COSV100519807; called by muse, varscan2
- PSMG1 | c.*57C>G | 3'UTR (SNP) | VAF 51/457 reads (11%) | called by muse, varscan2
- ZNF823 | c.-52G>A | 5'UTR (SNP) | VAF 197/1426 reads (14%) | catalogued as COSV100362499; called by muse, varscan2
